Somatic mutation profile of tumor specimen 0E0AQZ from CCDI case PBCUXU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0AQZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 629e7889-d5a1-46ef-8220-ae91a7c7032b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0AR9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3746ac9-763a-43f4-bdc1-614f08c18d20

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 256/308 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs398123317, CM061927, CM131940, CM981667, COSV64289561, COSV64292590; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANAPC7 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 273/627 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs61942589; called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs1400291275, COSV62280653; called by muse, mutect2, varscan2
- ST6GAL2 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 195/425 reads (46%) | PolyPhen possibly damaging (0.842); catalogued as rs1411040733, COSV62417053; called by muse, mutect2, varscan2
- UNC5C | c.1781G>T p.C594F | Missense Mutation (SNP) | VAF 222/501 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV71662784; called by muse, mutect2, varscan2
- KBTBD8 | c.987T>A p.I329= | Silent (SNP) | VAF 188/437 reads (43%) | called by muse, mutect2, varscan2
- ZNF860 | c.1512T>C p.H504= | Silent (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- ITPR1 | c.6785-51G>A | Intron (SNP) | VAF 27/67 reads (40%) | catalogued as rs1000820874; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- TMC2 | c.*32G>A | 3'UTR (SNP) | VAF 22/28 reads (79%) | catalogued as rs1244068848; called by mutect2, varscan2
- WAS | c.777+85G>A | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs781877730; called by muse, mutect2, varscan2
